CCDI case PBCLPT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/89fa3fcc-7648-4f42-9483-812aa80fd6c2

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Biospecimens (3 samples)
- Sample 0DXQJ9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXQJU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DYRPO: Tissue type: Tumor; Specimen type: Solid Tissue.
